EXCEPTIONAL_RESPONDERS case ER-ACXF — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/0f72c194-c923-4779-818a-fadc9e400d69

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1981; Vital status: Alive.

Diagnoses (1)
1. Glioblastoma multiforme: ICD-O-3 morphology code: 9440/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 25.7 years (9,390 days); Year of diagnosis: 2007; Prior malignancy: no; Days to last follow up: 2,845 days (7.8 years); Days to best overall response: 684 days (1.9 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Irinotecan; Days to treatment start: 270 days; Days to treatment end: 670 days (1.8 years).
   Treatment given: Therapeutic agents: Bevacizumab; Days to treatment start: 298 days; Days to treatment end: 3,030 days (8.3 years).

Follow-up (1 entry)
- Days to follow up: 2,845 days (7.8 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 217 days; Days progression-free: 2,845 days (7.8 years).

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-ACXF-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-ACXF-TTP1-A-1-0-S1: Section location: Top; Percent tumor cells: 60; Percent tumor nuclei: 85; Percent normal cells: 10; Percent necrosis: 0; Percent stromal cells: 30; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 1; Percent neutrophil infiltration: 0.
